Somatic mutation profile of tumor specimen 0DWD2B from CCDI case PBCNUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxoid chondrosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 25.0 years (9,117 days).
Specimen 0DWD2B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6eac69c-993a-479a-8c2c-d70040581d1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/915a51bf-7390-4dcb-9441-47d8f6dc01ec

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Intron 5, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HR | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 139/361 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.213); catalogued as rs138875411; called by muse, mutect2, varscan2
- KMT2D | c.6194A>G p.K2065R | Missense Mutation (SNP) | VAF 239/635 reads (38%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.609); catalogued as rs745309812; called by muse, mutect2, varscan2
- MOGAT3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 218/574 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs749808044; called by muse, mutect2, varscan2
- NF2 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 718/894 reads (80%) | catalogued as CM961039, COSV58529234; called by muse, mutect2, varscan2
- NOTCH3 | c.3940G>A p.A1314T | Missense Mutation (SNP) | VAF 91/343 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs764992581; called by muse, mutect2, varscan2
- SEC14L5 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 141/389 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs750795894, COSV52038106; called by muse, varscan2
- SLIT3 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 344/947 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.698); catalogued as rs372131562; called by muse, mutect2, varscan2
- SMARCB1 | c.694C>T p.Q232* (on ENST00000263121; = p.Q278* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 444/570 reads (78%) | catalogued as CM110778; called by muse, mutect2, varscan2
- SYT3 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 131/349 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58897224; called by muse, mutect2, varscan2
- C2orf78 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 309/806 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- COL25A1 | c.1845+1G>C p.X615_splice (on ENST00000399132 / NM_198721.4; = p.V616L on NM_032518.3) | Splice Site (SNP) | VAF 484/1282 reads (38%) | called by muse, mutect2
- TBL1X | c.928_932dup p.F311Lfs*17 | Frame Shift Ins (INS) | VAF 257/352 reads (73%) | called by mutect2, pindel, varscan2
- ADGRF5 | c.1707G>A p.L569= | Silent (SNP) | VAF 346/934 reads (37%) | called by muse, mutect2, varscan2
- CASZ1 | c.3597C>T p.A1199= | Silent (SNP) | VAF 109/882 reads (12%) | catalogued as rs375381763; called by muse, mutect2, varscan2
- CCT8 | c.1185T>G p.G395= | Silent (SNP) | VAF 273/1417 reads (19%) | called by muse, mutect2, varscan2
- MEDAG | c.57T>C p.S19= | Silent (SNP) | VAF 256/624 reads (41%) | called by muse, mutect2, varscan2
- OR5D16 | c.588C>A p.L196= | Silent (SNP) | VAF 451/1274 reads (35%) | called by muse, mutect2, varscan2
- SLC2A4 | c.273C>T p.G91= | Silent (SNP) | VAF 237/627 reads (38%) | catalogued as rs774374671; called by muse, mutect2, varscan2
- ALS2CL | c.2685-81C>T | Intron (SNP) | VAF 32/93 reads (34%) | catalogued as rs535944108; called by muse, mutect2
- ARMCX4 | c.1038+2950C>T | Intron (SNP) | VAF 174/204 reads (85%) | catalogued as rs868974687; called by muse, mutect2, varscan2
- DPH2 | c.-89T>C | 5'UTR (SNP) | VAF 89/219 reads (41%) | called by muse, mutect2, varscan2
- GTF2H1 | c.837+43C>G | Intron (SNP) | VAF 244/637 reads (38%) | called by muse, mutect2, varscan2
- MRPS2 | c.170-13C>T | Intron (SNP) | VAF 47/131 reads (36%) | catalogued as rs1486278152; called by muse, mutect2, varscan2
- MYO7A | c.6355-71C>A | Intron (SNP) | VAF 63/152 reads (41%) | called by mutect2, varscan2
